Somatic mutation profile of tumor specimen MP2PRT-PASUHZ-TMP1-A (aliquot MP2PRT-PASUHZ-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASUHZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,117 days).
Specimen MP2PRT-PASUHZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c55d7656-3116-4b35-a122-c5d8cae48cde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUHZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUHZ-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d265c9-cd27-4a86-99a2-329a0e57c040

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.3035G>A p.R1012Q (on ENST00000261722; = p.R1006Q on NM_004644.5) | Missense Mutation (SNP) | VAF 192/411 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs200505090; called by muse, mutect2, varscan2
- ARSF | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs1479802619, COSV63839983; called by muse, mutect2
- ATP2B3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs1342263352, COSV54850001; called by muse, mutect2
- CEACAM7 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs539835752; called by muse, mutect2, varscan2
- COL5A3 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 196/475 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as rs781654072; called by muse, mutect2, varscan2
- FREM3 | c.5018G>A p.R1673H | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs187342274, COSV61680251; called by muse, mutect2, varscan2
- GRIP2 | c.2129G>A p.R710H (on ENST00000619221; = p.R613H on NM_001080423.4) | Missense Mutation (SNP) | VAF 184/428 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs566897826, COSV56122631; called by muse, mutect2, varscan2
- GRM3 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 182/539 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs763037140, COSV64471749, COSV64480133; called by muse, mutect2, varscan2
- HAS1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 161/535 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs140981845; called by muse, mutect2, varscan2
- SLC23A3 | c.1739G>A p.G580D (on ENST00000409878 / NM_001144889.2; = p.G463D on NM_144712.5) | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1178698417; called by muse, mutect2
- TRO | c.3739G>A p.A1247T | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.217); catalogued as rs372056337, COSV51509028; called by muse, mutect2, varscan2
- ZIC4 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 93/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173086; called by muse, mutect2, varscan2
- ACTG2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.357); called by muse, mutect2
- ADSS1 | c.1225T>C p.W409R | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAGE12C | c.133del p.E45Nfs*61 | Frame Shift Del (DEL) | VAF 8/13 reads (62%) | called by mutect2, varscan2
- IGHV1-69 | chr14:106714682 TCT>CTCC | Missense Mutation (INS) | VAF 5/34 reads (15%) | called by pindel, varscan2*
- IGKV2D-30 | c.313_314insTCCG p.A105Vfs*3 | Frame Shift Ins (INS) | VAF 43/207 reads (21%) | called by pindel, varscan2
- IGKV2D-30 | chr2:89937677 del CCTCCCACAGTGGTA | Missense Mutation (DEL) | VAF 20/76 reads (26%) | called by pindel, varscan2
- LTBP1 | c.4999G>A p.D1667N (on ENST00000404816 / NM_206943.4; = p.D1341N on NM_000627.4) | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- MDGA2 | c.2998G>A p.D1000N (on ENST00000399232 / NM_001113498.2; = p.D702N on NM_182830.4) | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR2A12 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 161/376 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP11B | c.3333T>C p.N1111= | Silent (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- NRXN3 | c.2700G>A p.K900= (on ENST00000335750 / NM_001330195.2; = p.K527= on NM_004796.6) | Silent (SNP) | VAF 163/362 reads (45%) | called by muse, mutect2, varscan2
- ZCCHC13 | c.114T>C p.C38= | Silent (SNP) | VAF 223/387 reads (58%) | called by muse, mutect2, varscan2
